Gene-level copy-number profile of tumor specimen HCM-SANG-0296-C15-08A-01D-A80T-32 from HCMI case HCM-SANG-0296-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0296-C15-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fc7d842c-4da1-4acd-9ada-e1b768428ad0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0296-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,786 have no estimate.
https://portal.gdc.cancer.gov/files/70d61bd5-b9f0-4274-b70a-2767b539927d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 4,379; copy number 2: 50,464; copy number 3: 3,313; copy number 4: 451; copy number 5: 91; copy number 6: 99; copy number 7: 6; copy number 8: 15; copy number 9: 2; copy number 12: 4; copy number 15: 1; copy number 16: 2; copy number 21: 5.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:150,894,392–150,904,983, 1 gene (within-gene range 0–1): ZNF300.
- chr8:116,022,686–116,022,779, 1 gene (within-gene range 0–2): RNA5SP276.
- chr9:22,117,665–22,117,814, 1 gene (within-gene range 0–1): AL354709.2.
- chr9:117,685,254–117,685,588, 1 gene: RPL35AP22.
- chr12:18,738,119–18,739,188, 1 gene: CAPZA3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 225 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,173,880–1,251,334, 7 genes, copy number 5 (within-gene range 4–5): TTLL10, TNFRSF18, TNFRSF4, SDF4, B3GALT6, C1QTNF12, AL162741.1.
- chr1:77,944,055–77,979,110, 1 gene, copy number 5: FUBP1.
- chr1:189,666,149–189,666,256, 1 gene, copy number 7: RNA5SP73.
- chr2:90,038,848–90,122,564, 8 genes, copy number 5: IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14.
- chr2:90,172,802–91,621,421, 13 genes, copy number 5–9 (within-gene range 4–9): IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1.
- chr3:182,691,928–182,692,285, 1 gene, copy number 5: AC083801.1.
- chr4:106,836,498–106,837,601, 1 gene, copy number 6: ACTR6P1.
- chr5:18,908,866–18,909,543, 1 gene, copy number 5: AC114981.1.
- chr5:24,449,351–24,449,615, 1 gene, copy number 6: Metazoa_SRP.
- chr5:28,614,613–28,654,531, 2 genes, copy number 6: AC109472.1, RNU6-909P.
- chr8:143,915,153–143,976,734, 2 genes, copy number 5: PLEC, MIR661.
- chr9:42,579,414–42,714,539, 5 genes, copy number 5: BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1.
- chr9:60,914,407–60,964,196, 5 genes, copy number 21: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr9:63,703,065–63,762,824, 5 genes, copy number 5: AL591438.2, CDRT15P7, AL772155.1, AL772155.2, MYO5BP3.
- chr9:66,856,426–66,932,141, 2 genes, copy number 5: ZNF658, BX664608.1.
- chr9:67,697,076–68,531,061, 20 genes, copy number 5–8: Y_RNA, FAM27E3, AL627230.3, FAM27B, AL627230.1, RN7SL787P, SNORA70, AL627230.2, ANKRD20A1, RNU6-368P, AL353608.2, CBWD3, AL353608.4, FOXD4L3, AL353608.3, AL353608.1, PGM5, PGM5-AS1, AL161457.2, AL161457.1.
- chr9:136,359,480–136,400,168, 3 genes, copy number 5 (within-gene range 4–5): DNLZ, CARD9, SNAPC4.
- chr10:42,279,734–42,281,819, 1 gene, copy number 5: PABPC1P8.
- chr11:89,869,282–89,889,991, 3 genes, copy number 7: TRIM64B, AP005435.4, AP005435.2.
- chr11:89,911,111–89,949,402, 3 genes, copy number 6: TRIM49D1, TRIM49D2, AP004607.3.
- chr12:126,524,248–126,524,626, 1 gene, copy number 5: NDUFA5P6.
- chr13:85,968,999–85,969,533, 1 gene, copy number 7: MOB1AP1.
- chr14:18,333,726–18,602,129, 7 genes, copy number 6–12: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.13, CR383656.9, OR11H12.
- chr14:105,472,962–105,499,575, 4 genes, copy number 6: CRIP2, CRIP1, AL928654.3, TEDC1.
- chr14:105,583,731–105,601,728, 2 genes, copy number 5 (within-gene range 2–5): IGHA2, IGHE.
- chr16:527,712–800,737, 38 genes, copy number 5: CAPN15, MIR5587, MIR3176, Z97986.1, PRR35, PIGQ, NHLRC4, Z98883.1, RAB40C, WFIKKN1, METTL26, MCRIP2, AL022341.1, WDR90, AL022341.2, RHOT2, RHBDL1, LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1, FBXL16, Z97653.2, Z97653.1, METRN, ANTKMT, CCDC78, HAGHL, CIAO3, MSLN, AL031258.1, MSLNL, MIR662, RPUSD1, CHTF18, GNG13.
- chr16:975,761–1,113,399, 9 genes, copy number 5–8 (within-gene range 3–8): CEROX1, SOX8, AC009041.1, SSTR5-AS1, AC009041.2, SSTR5, C1QTNF8, AL031713.1, AL031598.1.
- chr16:88,382,959–88,537,031, 3 genes, copy number 5 (within-gene range 3–5): ZNF469, ZFPM1, MIR5189.
- chr18:70,289,045–70,330,199, 1 gene, copy number 5: SOCS6.
- chr21:7,744,962–13,120,807, 74 genes, copy number 6–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,523. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
